Gene-level copy-number profile of tumor specimen TCGA-EY-A2OQ-01A from TCGA case TCGA-EY-A2OQ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 61.1 years (22,309 days).
Specimen TCGA-EY-A2OQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.1677d55c-45e5-4749-a578-7db262323bb9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EY-A2OQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b54afbb9-302b-4f6e-8817-459501d0ecae

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 987; copy number 2: 5,512; copy number 3: 21,102; copy number 4: 18,374; copy number 5: 8,673; copy number 6: 1,657; copy number 7: 1,001; copy number 8: 1,264; copy number 9: 899; copy number 10: 2; copy number 11: 140; copy number 12: 118; copy number 13: 7; copy number 15: 38; copy number 16: 32; copy number 17: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EY-A2OQ-01A-11D-A19X-01): tumor purity 0.78, ploidy 3.89, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,237,358–181,265,145, 2 genes: AC019235.1, LINC02500.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,504 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:141,430,831–141,733,987, 3 genes, copy number 8: AC097504.2, LINC02276, IL15.
- chr4:149,351,709–154,828,813, 100 genes, copy number 9 (broad region; genes not listed).
- chr4:182,143,987–182,803,024, 1 gene, copy number 8 (within-gene range 6–8): TENM3.
- chr4:182,548,659–190,092,279, 169 genes, copy number 8 (broad region; genes not listed).
- chr8:46,870,902–145,066,685, 1,519 genes, copy number 8–9 (broad region; genes not listed).
- chr9:10,532,145–29,229,229, 233 genes, copy number 8–9 (broad region; genes not listed).
- chr11:79,092,848–79,612,300, 5 genes, copy number 8 (within-gene range 6–8): AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1.
- chr17:8,220,642–12,215,267, 96 genes, copy number 7 (broad region; genes not listed).
- chr17:26,981,694–29,404,105, 141 genes, copy number 8–16 (broad region; genes not listed).
- chr17:29,390,662–29,445,400, 3 genes, copy number 13: MIR4523, RNU6-711P, RNU6-1034P.
- chr17:30,378,927–30,527,592, 2 genes, copy number 10 (within-gene range 2–10): CPD, GOSR1.
- chr17:37,642,947–38,512,385, 23 genes, copy number 11: AC243571.2, AC243585.1, HNF1B, AC243571.1, YWHAEP7, RNU6-489P, TBC1D3K, 5S_rRNA, TBC1D3L, TBC1D3D, TBC1D3C, AC233968.1, Y_RNA, TBC1D3E, RNA5SP526, TBC1D3, NPEPPSP1, Y_RNA, MRPL45, GPR179, SOCS7, ARHGAP23, AC244153.1.
- chr17:47,844,908–79,088,599, 921 genes, copy number 7–12 (within-gene range 2–12) (broad region; genes not listed).
- chr17:79,132,722–79,136,402, 1 gene, copy number 7: AC021534.1.
- chr19:11,033,727–13,141,147, 158 genes, copy number 11–17 (broad region; genes not listed).
- chr19:14,689,801–17,075,625, 129 genes, copy number 9–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 987. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
